Somatic mutation profile of tumor specimen TCGA-PZ-A5RE-01A (aliquot TCGA-PZ-A5RE-01A-11D-A32N-08) from TCGA case TCGA-PZ-A5RE, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 44.5 years (16,255 days).
Specimen TCGA-PZ-A5RE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19e35fa5-3e1b-42c1-8e35-f4014a486fa6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PZ-A5RE-10B (Blood Derived Normal), aliquot TCGA-PZ-A5RE-10B-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b52c7c77-2585-4ac5-aa25-2f921f714f2c

The open-access MAF lists 28 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 4, Frame Shift Ins 2, RNA 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTBD11 | c.3008A>C p.K1003T (on ENST00000280758 / NM_001018072.2; = p.K540T on NM_001017523.2) | Missense Mutation (SNP) | VAF 123/217 reads (57%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen probably damaging (0.946); catalogued as COSV55025836, COSV55028973, COSV55038748; called by muse, mutect2, varscan2
- SMAD4 | c.1607T>C p.L536P | Missense Mutation (SNP) | VAF 124/392 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61686021, COSV61689552, COSV61689728, COSV61691591; called by muse, mutect2, varscan2
- TP53 | c.581T>A p.L194H | Missense Mutation (SNP) | VAF 55/203 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AARD | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 59/231 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV65600251; called by muse, mutect2, varscan2
- ABCB1 | c.3413G>T p.R1138L | Missense Mutation (SNP) | VAF 234/640 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99714747; called by muse, mutect2, varscan2
- ABCB5 | c.2410C>A p.Q804K (on ENST00000404938 / NM_001163941.2; = p.Q359K on NM_178559.6) | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV99330087; called by muse, mutect2, varscan2
- ANK1 | c.5623C>T p.H1875Y | Missense Mutation (SNP) | VAF 134/378 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as COSV99227248; called by muse, mutect2, varscan2
- AZGP1 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.124); catalogued as COSV99448285; called by muse, mutect2, varscan2
- CCDC120 | c.785C>A p.P262Q | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.593); catalogued as COSV100900738; called by muse, mutect2, varscan2
- DLGAP2 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.994); catalogued as rs370260485; called by muse, mutect2, varscan2
- DMBT1 | c.5729C>A p.S1910Y (on ENST00000338354 / NM_001377530.1; = p.S1153Y on NM_004406.3) | Missense Mutation (SNP) | VAF 230/866 reads (27%) | SIFT tolerated (1); PolyPhen probably damaging (0.947); catalogued as COSV100354414; called by muse, mutect2, varscan2
- DNAH7 | c.9814C>T p.R3272W | Missense Mutation (SNP) | VAF 78/263 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771631595, COSV100418123; called by muse, mutect2, varscan2
- DNAI2 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 113/434 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as rs1162547725, COSV56763303; called by muse, mutect2, varscan2
- LEPR | c.3296G>A p.R1099K | Missense Mutation (SNP) | VAF 62/238 reads (26%) | SIFT tolerated (0.97); PolyPhen benign (0.053); catalogued as rs1305997688, COSV100848447, COSV62746089; called by muse, mutect2, varscan2
- MAGEC1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 191/682 reads (28%) | catalogued as rs1381041660, COSV99596785; called by muse, mutect2, varscan2
- RB1CC1 | c.3512dup p.N1171Kfs*8 | Frame Shift Ins (INS) | VAF 33/162 reads (20%) | catalogued as rs756984292; called by mutect2, varscan2
- RCSD1 | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as rs749232188, COSV100827821; called by muse, varscan2
- RUNX1T1 | c.1418G>A p.R473Q (on ENST00000265814 / NM_001198628.1; = p.R446Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/328 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as rs774408067, COSV56146644; called by muse, mutect2, varscan2
- SLC9A5 | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 70/267 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.397); catalogued as rs769149966, COSV55361671; called by muse, mutect2, varscan2
- SRC | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 238/946 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100658273; called by muse, mutect2, varscan2
- SSBP4 | c.1148T>C p.M383T | Missense Mutation (SNP) | VAF 106/504 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV99526398; called by muse, mutect2, varscan2
- PPP2R5C | c.620dup p.F208Ifs*3 | Frame Shift Ins (INS) | VAF 142/662 reads (21%) | called by mutect2, pindel, varscan2
- SLC22A5 | c.958_961delinsT p.D320del | In Frame Del (DEL) | VAF 35/262 reads (13%) | called by pindel, varscan2*
- ACTL9 | c.1011C>T p.N337= | Silent (SNP) | VAF 101/378 reads (27%) | catalogued as rs782009335, COSV100185599; called by muse, mutect2, varscan2
- ATP2B3 | c.834C>T p.A278= | Silent (SNP) | VAF 156/560 reads (28%) | catalogued as rs782744724, COSV99686201; called by muse, mutect2, varscan2
- PCDHB10 | c.1707C>T p.S569= | Silent (SNP) | VAF 26/186 reads (14%) | catalogued as rs1390094334; called by mutect2, varscan2
- SHROOM4 | c.408C>T p.D136= | Silent (SNP) | VAF 61/201 reads (30%) | catalogued as rs1299682253, COSV56785578; called by muse, mutect2, varscan2
- DCHS2 | n.5002C>T | RNA (SNP) | VAF 87/285 reads (31%) | catalogued as rs764516666, COSV61768166; called by muse, mutect2, varscan2
